Somatic mutation profile of tumor specimen TCGA-ZF-AA5H-01A (aliquot TCGA-ZF-AA5H-01A-11D-A391-08) from TCGA case TCGA-ZF-AA5H, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.6 years (22,122 days).
Specimen TCGA-ZF-AA5H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da20a5fd-0fe7-41b2-996b-2bc474a8aa3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA5H-10A (Blood Derived Normal), aliquot TCGA-ZF-AA5H-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bf7f691-8110-4e1d-8716-bf2cd7ced706

The open-access MAF lists 69 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Nonsense Mutation 3, Splice Site 2, Intron 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2325+1G>A p.X775_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as rs1131690882, CS058012, COSV57302937, COSV57317467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 31/39 reads (79%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ADGRB1 | c.1062C>G p.D354E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1210970442, COSV60102680; called by muse, mutect2, varscan2
- AFF1 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57123370; called by muse, mutect2, varscan2
- ALYREF | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs1280360311, COSV100485905; called by muse, mutect2
- ANK2 | c.8221T>A p.S2741T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52184426; called by muse, mutect2, varscan2
- B3GNT4 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs1424495821, COSV57337331; called by muse, mutect2, varscan2
- BRD8 | c.1598G>T p.S533I (on ENST00000254900 / NM_139199.2; = p.S606I on NM_006696.4) | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV50165777; called by muse, mutect2, varscan2
- COBL | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs749249733, COSV54344223; called by muse, mutect2, varscan2
- DCLK2 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV56210916; called by muse, mutect2, varscan2
- DMD | c.4317A>T p.R1439S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV63786815; called by muse, mutect2, varscan2
- DYNC1H1 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64141651; called by muse, mutect2, varscan2
- ENTPD5 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as COSV58223817; called by muse, mutect2, varscan2
- FARP1 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV60346392; called by muse, mutect2, varscan2
- FUT10 | c.1068G>C p.K356N | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV59453905; called by muse, mutect2, varscan2
- FUT10 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV59453920; called by muse, mutect2, varscan2
- FUT10 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59453931; called by muse, mutect2, varscan2
- FUT10 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as COSV59449850; called by muse, varscan2
- GABRD | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376054712; called by muse, mutect2, varscan2
- GALNT3 | c.1721G>T p.C574F | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67062381; called by muse, mutect2, varscan2
- GMDS | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.051); catalogued as COSV66440945; called by muse, mutect2, varscan2
- GSTK1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV64424647; called by muse, mutect2, varscan2
- IGF2BP1 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV51730409, COSV51735306; called by muse, mutect2
- ITIH6 | c.1777C>T p.L593F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV54493872; called by muse, mutect2, varscan2
- KIF21A | c.2671G>T p.A891S (on ENST00000361418 / NM_001378440.1; = p.A878S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV62777195; called by muse, mutect2, varscan2
- KIRREL1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1558013087, COSV63290745; called by muse, mutect2, varscan2
- LAMA1 | c.4002-2A>C p.X1334_splice | Splice Site (SNP) | VAF 22/223 reads (10%) | catalogued as COSV67543495; called by muse, mutect2, varscan2
- MET | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs761808213, CM068008, COSV59258286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDUFB5 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV52021682; called by muse, mutect2, varscan2
- NOS1 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760598926, COSV57615895; called by muse, mutect2, varscan2
- NOVA1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57477575; called by muse, mutect2
- OR5H15 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV100736785; called by muse, mutect2
- OR7C2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs765714556, COSV50181808; called by muse, mutect2, varscan2
- PFKFB1 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | PolyPhen possibly damaging (0.854); catalogued as COSV51506907, COSV99436111; called by muse, mutect2
- PKN1 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54402858; called by muse, mutect2
- RNF213 | c.14935C>G p.L4979V | Missense Mutation (SNP) | VAF 158/282 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60407587; called by muse, varscan2
- SEMA4C | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.93); catalogued as rs1444526404, COSV59692139; called by muse, mutect2, varscan2
- SHROOM3 | c.5707C>T p.R1903* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV56031526; called by muse, mutect2, varscan2
- SLCO5A1 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99481174; called by muse, mutect2, varscan2
- SPDEF | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV65000730, COSV65001503; called by muse, mutect2, varscan2
- SPTBN4 | c.5593G>A p.E1865K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.446); catalogued as rs747435937, COSV58951756; called by muse, mutect2, varscan2
- SYT4 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54903702; called by muse, mutect2, varscan2
- THSD7B | c.4447T>C p.F1483L (on ENST00000272643; = p.F1481L on NM_001316349.2) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as COSV99758831; called by muse, mutect2
- TOX4 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV52971022; called by muse, mutect2, varscan2
- TSC1 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV53772264; called by muse, mutect2, varscan2
- WWOX | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV68366959; called by muse, mutect2, varscan2
- ZNF398 | c.1690G>A p.E564K (on ENST00000475153 / NM_170686.3; = p.E393K on NM_020781.4) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60066535; called by muse, mutect2, varscan2
- ZNF862 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV56225806; called by muse, mutect2, varscan2
- PICALM | c.1381dup p.R461Kfs*6 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1935C>T p.L645= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV55295755, COSV55297479; called by muse, mutect2, varscan2
- CYP2C8 | c.585C>T p.L195= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs530468858, COSV64878684; called by muse, mutect2, varscan2
- DNAJC16 | c.1131G>C p.V377= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV101012599, COSV65449369; called by muse, mutect2, varscan2
- EPDR1 | c.627G>A p.T209= | Silent (SNP) | VAF 97/117 reads (83%) | catalogued as rs750392270, COSV52261667; called by muse, mutect2, varscan2
- FARP1 | c.765C>T p.F255= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV60346406; called by muse, varscan2
- FARP1 | c.840C>G p.L280= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV60346425; called by muse, varscan2
- FLT3 | c.1338G>A p.S446= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs146109614; called by muse, mutect2, varscan2
- GNA11 | c.984C>T p.F328= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs747189004, COSV50031474; called by muse, mutect2, varscan2
- HERC2 | c.10323G>A p.A3441= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs765221410, COSV55305858; called by muse, mutect2, varscan2
- MAP3K2 | c.897G>C p.V299= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV61296020; called by muse, mutect2, varscan2
- PCDHA8 | c.1536G>A p.T512= | Silent (SNP) | VAF 67/122 reads (55%) | catalogued as COSV65331912; called by muse, mutect2, varscan2
- PCIF1 | c.150G>A p.E50= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV65027129; called by muse, mutect2, varscan2
- POTEE | c.1929C>T p.D643= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs371706116; called by muse, mutect2, varscan2
- PTPN22 | c.183G>A p.K61= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as COSV63086374; called by muse, mutect2, varscan2
- RIC1 | c.3879C>T p.I1293= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV52614547; called by muse, mutect2, varscan2
- RIMBP2 | c.2319G>A p.G773= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV55482786; called by muse, mutect2, varscan2
- RPS6KA5 | c.1791C>T p.N597= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs139792854, COSV56222323; called by muse, mutect2, varscan2
- TMEM207 | c.241C>A p.R81= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV61561508, COSV61562220; called by muse, mutect2
- AFDN | chr6:167826157 C>T | 5'Flank (SNP) | VAF 21/93 reads (23%) | catalogued as rs1298103350; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2045C>T | Intron (SNP) | VAF 9/97 reads (9%) | catalogued as COSV100678852; called by muse, mutect2
